Somatic mutation profile of tumor specimen MMRF_1148_1_BM_CD138pos (aliquot MMRF_1148_1_BM_CD138pos_T1_KAS5U_L01705) from MMRF case MMRF_1148, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.3 years (26,036 days).
Specimen MMRF_1148_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67db7572-9d4c-4ed1-a278-5481051e959b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1148_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1148_1_PB_Whole_C2_KAS5U_L01713; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d75dfd7-a530-485f-8359-c62f1f8c2d1a

The open-access MAF lists 136 somatic variants for this specimen: 44 protein-altering or splice-affecting, 13 silent, 79 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 49, Missense Mutation 37, Intron 17, Silent 13, 5'UTR 6, 3'Flank 4, RNA 2, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- AP5Z1 | c.1285A>G p.R429G | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV100804106; called by muse, mutect2, varscan2
- COL6A1 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.102); catalogued as rs765826390, COSV62615268; called by muse, mutect2, varscan2
- F13A1 | c.1165G>A p.G389R | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99343169; called by muse, mutect2, varscan2
- H1-5 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs754859751; called by muse, mutect2, varscan2
- IGHV2-70 | c.261G>C p.R87S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs371189824; called by muse, varscan2
- IGLL5 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 21/22 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs767386322, COSV73250551; called by muse, mutect2, varscan2
- IGLV1-40 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.047); catalogued as rs187953594; called by muse, varscan2
- IGLV1-44 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.105); catalogued as rs775827638; called by muse, mutect2, varscan2
- IGLV2-14 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.179); catalogued as rs180790211; called by muse, mutect2, varscan2
- IGLV3-1 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 30/30 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs142180628; called by muse, varscan2
- MOGS | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV51970387; called by muse, mutect2, varscan2
- NEUROD1 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.439); catalogued as rs759416733; called by muse, mutect2, varscan2
- NWD2 | c.4366A>G p.K1456E | Missense Mutation (SNP) | VAF 79/149 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs904530364; called by muse, mutect2, varscan2
- OTUD6A | c.69G>T p.Q23H | Missense Mutation (SNP) | VAF 65/68 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV57972858; called by muse, mutect2, varscan2
- RNPEPL1 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.287); catalogued as rs1334874721; called by muse, mutect2, varscan2
- SH2D5 | c.1213C>T p.R405W (on ENST00000444387 / NM_001103161.2; = p.R321W on NM_001103160.2) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs368970937; called by muse, mutect2, varscan2
- TEP1 | c.4861C>T p.P1621S | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774227713; called by muse, mutect2, varscan2
- TMEM169 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559229892; called by muse, mutect2, varscan2
- ZNF865 | c.1147T>A p.C383S | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); catalogued as COSV101642838; called by muse, mutect2
- CCDC38 | c.117_126del p.N39Kfs*9 | Frame Shift Del (DEL) | VAF 66/163 reads (40%) | called by mutect2, pindel, varscan2
- CEP83 | c.174G>T p.R58S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- CHD7 | c.3177T>A p.Y1059* | Nonsense Mutation (SNP) | VAF 79/167 reads (47%) | called by muse, mutect2, varscan2
- CREB1 | c.617C>T p.T206I (on ENST00000432329 / NM_134442.5; = p.T192I on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- DDX60 | c.2612T>G p.L871R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSPA8 | c.91A>G p.N31D | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- IGHV2-70 | c.339_341delinsTT p.Y114Ffs*? | Frame Shift Del (DEL) | VAF 22/39 reads (56%) | called by pindel, varscan2*
- IGHV2-70D | c.166A>C p.S56R | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.513); called by muse, varscan2
- IGLL5 | c.288_294delinsG p.C96_V98delinsW | In Frame Del (DEL) | VAF 47/49 reads (96%) | called by pindel, varscan2*
- ITPR1 | c.6848T>G p.L2283R (on ENST00000354582; = p.L2228R on NM_002222.7) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP20-3 | c.124G>T p.V42L | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR51E2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OVCH2 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- PAM | c.2699A>G p.H900R (on ENST00000438793 / NM_001319943.1; = p.H901R on NM_000919.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHOX2A | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2
- PRRC2C | c.6032-1G>A p.X2011_splice (on ENST00000367742; = p.X2009_splice on NM_015172.4) | Splice Site (SNP) | VAF 104/173 reads (60%) | called by muse, mutect2, varscan2
- STAT5B | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- STOX2 | c.2511A>C p.R837S | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- TENM2 | c.431T>G p.L144R | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- TENT5C | c.714A>C p.E238D | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TMSB10 | c.78G>C p.K26N | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VPS13D | c.8987A>T p.Y2996F | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.214); called by muse, varscan2
- ZNF485 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- ZSCAN4 | c.1276G>A p.V426I | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C17orf100 | c.13C>A p.R5= | Silent (SNP) | VAF 46/71 reads (65%) | catalogued as rs750777843; called by muse, mutect2, varscan2
- GPER1 | c.1074C>T p.A358= | Silent (SNP) | VAF 95/146 reads (65%) | catalogued as rs745918553; called by muse, mutect2, varscan2
- H2BC10 | c.304C>T p.L102= | Silent (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- IGHA1 | c.261G>A p.V87= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1458064586; called by muse, mutect2, varscan2
- IGHV2-70D | c.138C>T p.F46= | Silent (SNP) | VAF 26/28 reads (93%) | called by muse, varscan2
- IGLC7 | c.276A>G p.E92= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- IGLV1-40 | c.66G>A p.V22= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as rs368418521; called by muse, varscan2
- IGLV1-40 | c.165C>T p.H55= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as rs765954501; called by muse, varscan2
- IGLV2-14 | c.354C>G p.L118= | Silent (SNP) | VAF 16/16 reads (100%) | called by muse, mutect2, varscan2
- INPP4B | c.2661G>A p.E887= | Silent (SNP) | VAF 72/154 reads (47%) | called by muse, mutect2, varscan2
- PCDHB6 | c.2292C>T p.F764= | Silent (SNP) | VAF 48/196 reads (24%) | catalogued as COSV50690426; called by muse, mutect2, varscan2
- STK31 | c.993A>G p.V331= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs1236676703; called by muse, mutect2, varscan2
- TEX2 | c.1134A>G p.R378= | Silent (SNP) | VAF 35/113 reads (31%) | called by muse, mutect2, varscan2
- AC114741.1 | n.278G>A | RNA (SNP) | VAF 6/20 reads (30%) | catalogued as rs749476332; called by mutect2, varscan2
- AC134980.2 | c.-788+50C>A | Intron (SNP) | VAF 49/242 reads (20%) | called by muse, mutect2, varscan2
- ADORA1 | c.*1249C>A | 3'UTR (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- AP3S1 | c.-50C>T | 5'UTR (SNP) | VAF 25/60 reads (42%) | catalogued as rs774362428; called by muse, mutect2, varscan2
- ARAP3 | c.973-122A>G | Intron (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- ARID4B | c.*857T>C | 3'UTR (SNP) | VAF 57/91 reads (63%) | called by muse, mutect2, varscan2
- ASAP2 | c.*1606G>C | 3'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- BMP3 | c.*1385C>T | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81949108 G>A | 3'Flank (SNP) | VAF 46/151 reads (30%) | called by muse, mutect2, varscan2
- CAPN1 | c.2118+48G>A | Intron (SNP) | VAF 14/43 reads (33%) | catalogued as rs770668658; called by muse, mutect2, varscan2
- CASP8 | c.1-8119del | Intron (DEL) | VAF 37/64 reads (58%) | called by mutect2, pindel, varscan2
- CCDC93 | c.1729-86T>G | Intron (SNP) | VAF 25/49 reads (51%) | catalogued as rs910020620; called by muse, mutect2, varscan2
- CDH2 | c.*513G>A | 3'UTR (SNP) | VAF 43/133 reads (32%) | called by muse, mutect2, varscan2
- CDH8 | c.*456A>G | 3'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2
- CLIC4 | c.*1670C>T | 3'UTR (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- COL4A2 | c.648+281C>T | Intron (SNP) | VAF 8/24 reads (33%) | catalogued as rs1009951817; called by muse, mutect2
- DCAF4L1 | c.*2192C>T | 3'UTR (SNP) | VAF 22/48 reads (46%) | catalogued as rs889171753; called by muse, varscan2
- DLG2 | c.*3210T>G | 3'UTR (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- DNAJC15 | c.*610G>A | 3'UTR (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- DOCK3 | c.*1900T>G | 3'UTR (SNP) | VAF 62/94 reads (66%) | called by muse, mutect2, varscan2
- EFCAB2 | c.*2090T>C | 3'UTR (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- ETS1 | c.-33C>T | 5'UTR (SNP) | VAF 44/98 reads (45%) | called by muse, varscan2
- ETS1 | c.-76C>G | 5'UTR (SNP) | VAF 51/105 reads (49%) | called by muse, varscan2
- FMO4 | c.*68C>G | 3'UTR (SNP) | VAF 109/157 reads (69%) | called by muse, mutect2, varscan2
- GABRA2 | c.187+22080G>A | Intron (SNP) | VAF 35/75 reads (47%) | catalogued as rs1291065458; called by muse, mutect2, varscan2
- GIMAP5 | c.*531G>A | 3'UTR (SNP) | VAF 58/135 reads (43%) | called by muse, mutect2, varscan2
- GPR153 | c.*876G>A | 3'UTR (SNP) | VAF 26/64 reads (41%) | catalogued as rs1384005156; called by muse, mutect2, varscan2
- GRIK3 | c.*68C>T | 3'UTR (SNP) | VAF 14/23 reads (61%) | catalogued as rs187698007; called by muse, mutect2, varscan2
- GRM5 | c.*560G>A | 3'UTR (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- IMPDH2 | c.99-34_99-26del | Intron (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- KIF1C | c.*1994C>T | 3'UTR (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- KRTAP4-11 | c.*119A>T | 3'UTR (SNP) | VAF 39/146 reads (27%) | catalogued as COSV101194973; called by muse, mutect2, varscan2
- LNX1 | c.380+15459C>G | Intron (SNP) | VAF 16/33 reads (48%) | catalogued as COSV55790581; called by muse, mutect2, varscan2
- LRRC74B | c.415+33G>A | Intron (SNP) | VAF 21/42 reads (50%) | catalogued as rs772010073; called by muse, mutect2, varscan2
- MCM9 | c.*776G>T | 3'UTR (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- MIPOL1 | c.*3089T>G | 3'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- MTMR11 | c.1290+122C>T | Intron (SNP) | VAF 6/17 reads (35%) | catalogued as rs149829057; called by muse, mutect2, varscan2
- NAA40 | c.*2086G>A | 3'UTR (SNP) | VAF 13/33 reads (39%) | catalogued as rs1303457519; called by muse, mutect2, varscan2
- NAPEPLD | c.*6-115del | Intron (DEL) | VAF 54/190 reads (28%) | called by mutect2, pindel, varscan2
- NOP56 | c.1011-176T>A | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, varscan2
- ONECUT2 | c.*1982G>A | 3'UTR (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- PBLD | c.*75C>G | 3'UTR (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- PCDH17 | c.*919A>C | 3'UTR (SNP) | VAF 39/64 reads (61%) | called by muse, mutect2, varscan2
- PPP1R8 | c.-36G>A | 5'UTR (SNP) | VAF 15/34 reads (44%) | catalogued as rs1392221396; called by muse, mutect2, varscan2
- PRDX4 | c.*5T>A | 3'UTR (SNP) | VAF 39/39 reads (100%) | called by muse, mutect2, varscan2
- PTPN3 | c.*3155T>C | 3'UTR (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- RBBP9 | c.*1270C>T | 3'UTR (SNP) | VAF 8/14 reads (57%) | catalogued as rs1020686245; called by muse, mutect2, varscan2
- RER1 | chr1:2404815 C>T | 3'Flank (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- RETREG2 | c.419+131G>A | Intron (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- RORA | c.*2662T>G | 3'UTR (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- RPL23A | c.25+115C>T | Intron (SNP) | VAF 6/33 reads (18%) | catalogued as rs560494257; called by muse, mutect2, varscan2
- SLC13A1 | c.*1413T>A | 3'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- SLC14A1 | c.*80T>C | 3'UTR (SNP) | VAF 99/294 reads (34%) | called by muse, mutect2, varscan2
- SLC1A2 | c.*9130G>A | 3'UTR (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- SLC25A36 | c.*264T>G | 3'UTR (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- SLC27A4 | c.*61G>A | 3'UTR (SNP) | VAF 29/83 reads (35%) | catalogued as rs1294805779; called by muse, mutect2, varscan2
- SLC6A11 | c.*86G>A | 3'UTR (SNP) | VAF 86/264 reads (33%) | called by muse, mutect2, varscan2
- SPATA31D4 | c.*63G>A | 3'UTR (SNP) | VAF 44/165 reads (27%) | called by muse, mutect2, varscan2
- SRRM4 | c.*946G>A | 3'UTR (SNP) | VAF 41/112 reads (37%) | catalogued as rs868413079; called by muse, mutect2, varscan2
- SSPOP | n.9506G>A | RNA (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2
- SVIP | c.*2911G>A | 3'UTR (SNP) | VAF 32/76 reads (42%) | catalogued as rs1182373614; called by muse, mutect2, varscan2
- TERB2 | c.*441T>C | 3'UTR (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- TFDP2 | c.*376G>A | 3'UTR (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
- TIGIT | c.*774T>C | 3'UTR (SNP) | VAF 63/93 reads (68%) | catalogued as rs931251919; called by muse, mutect2, varscan2
- TMSB4X | chrX:12975608 del CCTTCTTGCAG | 5'Flank (DEL) | VAF 29/34 reads (85%) | called by mutect2, pindel, varscan2
- TPP2 | chr13:102678648 T>G | 3'Flank (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- TRAT1 | c.152+59C>A | Intron (SNP) | VAF 34/42 reads (81%) | called by muse, mutect2, varscan2
- TRIM33 | c.*2661T>G | 3'UTR (SNP) | VAF 54/113 reads (48%) | called by muse, mutect2, varscan2
- USP37 | c.*1790T>G | 3'UTR (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- UTRN | c.*1412_*1428del | 3'UTR (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- ZC3H12C | c.*4921A>G | 3'UTR (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- ZFP36L2 | c.*1205T>G | 3'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- ZIC1 | c.-117C>T | 5'UTR (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- ZNF385D | c.*432A>T | 3'UTR (SNP) | VAF 47/69 reads (68%) | called by muse, mutect2, varscan2
- ZNF419 | c.*511T>C | 3'UTR (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- ZNF711 | chrX:85271946 C>A | 3'Flank (SNP) | VAF 76/76 reads (100%) | catalogued as rs907642064; called by muse, mutect2, varscan2
- ZNF736 | c.-149C>T | 5'UTR (SNP) | VAF 52/151 reads (34%) | catalogued as rs778095292; called by muse, mutect2, varscan2
- ZNF839 | c.844-90G>A | Intron (SNP) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- ZNRF3 | c.*2039C>T | 3'UTR (SNP) | VAF 36/89 reads (40%) | catalogued as rs542529019; called by muse, mutect2
